CPTAC case C685110 — Breast — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/ceb41bc0-5d1e-4120-8325-48aa08871d77

Demographics
Sex at birth: female; Age at index: 37 years; Vital status: Dead; Days to death: 226 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Intraductal carcinoma, NOS: ICD-O-3 morphology code: 8500/2; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Cerebrum; Last known disease status: With tumor; Days to last known disease status: 226 days; Progression or recurrence: yes; Days to recurrence: 162 days; Sites of involvement: Brain, Cerebrum; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Pack years smoked: 0; Cigarettes per day: 30; Alcohol history: Yes.

Biospecimens (7 samples)
- Samples 1104801, 1104817, 1105197, 1105266, SM-JU32S, SM-JU356 (6 with the same recorded description): Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Biospecimen laterality: Left; Preservation method: Snap Frozen.
- Sample 1105277: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
